Somatic mutation profile of tumor specimen MP2PRT-PARNFH-TMP1-A (aliquot MP2PRT-PARNFH-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARNFH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,118 days).
Specimen MP2PRT-PARNFH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0576bb9-6b7c-438f-b007-c08cf7ddcdbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNFH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNFH-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15266aed-cf50-40af-8d38-36536ac4ba21

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 38/151 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP3B2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs373196064, COSV55608496; called by muse, varscan2
- CCDC120 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 317/1315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782019146; called by muse, varscan2
- CELSR1 | c.8405G>A p.G2802D | Missense Mutation (SNP) | VAF 116/289 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1261593053; called by muse, mutect2, varscan2
- FBN1 | c.1146C>T p.T382= | Splice Region (SNP) | VAF 88/260 reads (34%) | catalogued as rs889875676, COSV57319920; ClinVar: likely benign; called by muse, varscan2
- GABRB3 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.035); catalogued as rs768585073, COSV59482279; called by muse, mutect2, varscan2
- NCBP3 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 182/357 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs767928576, COSV50108452; called by muse, mutect2, varscan2
- SEL1L3 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1229331983, COSV53545257; called by muse, mutect2, varscan2
- ARHGAP6 | c.2915C>T p.T972M (on ENST00000337414 / NM_013427.3; = p.T769M on NM_013423.3) | Missense Mutation (SNP) | VAF 157/648 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- CDK17 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KMT2D | c.4816del p.S1606Hfs*116 | Frame Shift Del (DEL) | VAF 206/605 reads (34%) | called by mutect2, pindel, varscan2
- LZTS2 | c.238A>T p.R80W | Missense Mutation (SNP) | VAF 260/906 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CACNA1H | c.2499C>G p.T833= | Silent (SNP) | VAF 176/472 reads (37%) | catalogued as rs1567523080; called by muse, mutect2, varscan2
- CDH22 | c.402G>A p.T134= | Silent (SNP) | VAF 222/654 reads (34%) | catalogued as rs752285113; called by muse, varscan2
- LTBP1 | c.3912C>T p.N1304= (on ENST00000404816 / NM_206943.4; = p.N978= on NM_000627.4) | Silent (SNP) | VAF 176/478 reads (37%) | catalogued as rs761211292, COSV55383369; called by muse, mutect2
- NYAP2 | c.1812G>A p.A604= | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as rs989073141; called by muse, mutect2, varscan2
- PALMD | c.303G>A p.T101= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs1052572897; called by muse, mutect2, varscan2
- SLC6A5 | c.1566C>T p.S522= | Silent (SNP) | VAF 119/370 reads (32%) | catalogued as rs762275099, COSV54225937; called by muse, varscan2
